CCDI case PBBLLP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/07740349-72a2-440f-aeff-2ac2db90ee4a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Embryonal sarcoma: ICD-O-3 morphology code: 8991/3; Tissue or organ of origin: Liver; Age at diagnosis: 11.9 years (4,340 days).

Biospecimens (3 samples)
- Samples 0DC29I, 0DC2A3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC29O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
